Somatic mutation profile of tumor specimen MMRF_2058_1_BM_CD138pos (aliquot MMRF_2058_1_BM_CD138pos_T1_KHS5U_L08081) from MMRF case MMRF_2058, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.9 years (23,324 days).
Specimen MMRF_2058_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef1e1c6a-b467-4825-bd6c-176834304dc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2058_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2058_1_PB_Whole_C1_KHS5U_L08082; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22dde743-8e82-4920-838b-6c8c78abfc99

The open-access MAF lists 65 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 18, Silent 7, Intron 7, Nonsense Mutation 3, Splice Region 2, 3'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPE | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.585); catalogued as COSV99247639; called by muse, mutect2, varscan2
- CFAP54 | c.5446G>T p.E1816* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100733423; called by muse, mutect2, varscan2
- COL5A3 | c.3237G>A p.G1079= | Splice Region (SNP) | VAF 77/359 reads (21%) | catalogued as rs1208491762; called by muse, mutect2, varscan2
- IGHJ6 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 22/54 reads (41%) | PolyPhen benign (0.069); catalogued as rs368585758; called by muse, varscan2
- IGHV2-70 | c.157A>C p.M53L | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs369368857; called by muse, varscan2
- MKI67 | c.5351C>T p.T1784I | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.426); catalogued as rs780760445, COSV100896858; called by muse, mutect2, varscan2
- MPDZ | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 120/173 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376910496; called by muse, mutect2, varscan2
- RHPN2 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs557723953; called by muse, varscan2
- SAMD1 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1341265604; called by muse, mutect2, varscan2
- ZBBX | c.1274G>T p.S425I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100285054; called by muse, mutect2, varscan2
- CELSR3 | c.4123G>A p.D1375N | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CEP170 | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.418); called by muse, mutect2
- DHODH | c.47T>C p.I16T | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- DPP10 | c.1473A>T p.L491F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPPA2 | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 64/185 reads (35%) | called by muse, mutect2, varscan2
- GLP2R | c.593C>A p.T198N | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- IGKJ1 | c.31_34delinsCGTG p.E11_I12delinsDV | Missense Mutation (ONP) | VAF 20/110 reads (18%) | called by muse*, pindel
- LARP6 | c.702A>C p.K234N | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- LRP1 | c.7917C>T p.C2639= | Splice Region (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- LRP4 | c.317C>A p.P106H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); called by mutect2, varscan2
- MTTP | c.1766C>A p.A589E | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- PHC3 | c.1070A>G p.N357S (on ENST00000494943 / NM_001308116.2; = p.N369S on NM_024947.4) | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC17A6 | c.422C>G p.P141R | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRAF3 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- TRIM3 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.389); called by muse, mutect2
- TRIM49B | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- UGT1A3 | c.50T>G p.L17R | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USF3 | c.1843T>C p.S615P | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZFP28 | c.1928A>C p.K643T | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF248 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ABCA9 | c.2637T>G p.L879= | Silent (SNP) | VAF 41/58 reads (71%) | called by muse, mutect2, varscan2
- C16orf96 | c.1815C>T p.A605= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as rs1028677438; called by muse, mutect2, varscan2
- DSTYK | c.459C>T p.L153= | Silent (SNP) | VAF 7/151 reads (5%) | called by muse, mutect2
- EFEMP2 | c.888G>A p.E296= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as rs1275525674; called by muse, mutect2, varscan2
- GRIN2B | c.4104C>T p.G1368= | Silent (SNP) | VAF 49/94 reads (52%) | catalogued as rs200021190; called by muse, mutect2, varscan2
- IGHV2-70D | c.228T>C p.D76= | Silent (SNP) | VAF 26/92 reads (28%) | called by muse, varscan2
- RHBDL2 | c.189G>A p.L63= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- ARHGEF3 | c.1228+254T>A | Intron (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- C21orf91 | c.*170T>A | 3'UTR (SNP) | VAF 50/96 reads (52%) | called by muse, mutect2, varscan2
- CFAP65 | c.1385-121G>C | Intron (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- CHRDL1 | c.*2022A>C | 3'UTR (SNP) | VAF 31/32 reads (97%) | called by muse, mutect2, varscan2
- CMIP | c.1531-110C>G | Intron (SNP) | VAF 16/38 reads (42%) | catalogued as rs1427028015; called by muse, mutect2, varscan2
- COL6A1 | c.*617G>A | 3'UTR (SNP) | VAF 12/240 reads (5%) | catalogued as rs957655561, COSV62614049; called by muse, mutect2
- DBNL | c.*7092T>C | 3'UTR (SNP) | VAF 40/64 reads (63%) | called by muse, mutect2, varscan2
- DSCR4 | n.767A>C | RNA (SNP) | VAF 76/181 reads (42%) | called by muse, mutect2, varscan2
- DUOX2 | c.*988G>T | 3'UTR (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- FADS1 | c.*854T>C | 3'UTR (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- GRIN2A | c.*2100A>T | 3'UTR (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- ICE2 | c.1125+621C>T | Intron (SNP) | VAF 18/29 reads (62%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.1471+15912A>T | Intron (SNP) | VAF 43/77 reads (56%) | called by muse, mutect2
- LRRTM4 | c.1551+348T>G | Intron (SNP) | VAF 45/63 reads (71%) | called by muse, mutect2, varscan2
- OSBP | c.*829C>G | 3'UTR (SNP) | VAF 45/69 reads (65%) | called by muse, mutect2, varscan2
- PACRG | c.613+101329A>C | Intron (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100434267; called by muse, mutect2
- RAB3IP | c.*3051G>C | 3'UTR (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- RPH3AL | c.*209A>G | 3'UTR (SNP) | VAF 5/18 reads (28%) | catalogued as rs1446156224; called by muse, mutect2
- RPS6KA2 | c.*572G>A | 3'UTR (SNP) | VAF 135/220 reads (61%) | catalogued as rs746026870; called by muse, mutect2, varscan2
- S100A7A | chr1:153421983 del G | 3'Flank (DEL) | VAF 51/191 reads (27%) | called by mutect2, pindel, varscan2
- SLC13A1 | c.*827C>T | 3'UTR (SNP) | VAF 21/52 reads (40%) | catalogued as rs569343088; called by muse, mutect2, varscan2
- TARDBP | c.*224G>C | 3'UTR (SNP) | VAF 70/226 reads (31%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-3C>T | 5'UTR (SNP) | VAF 10/88 reads (11%) | catalogued as rs776687705, COSV56552223; called by muse, mutect2, varscan2
- TBX18 | c.*1658del | 3'UTR (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- TMEM41A | c.*1822C>G | 3'UTR (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- UBE2D2 | c.*1327A>G | 3'UTR (SNP) | VAF 38/124 reads (31%) | catalogued as rs561145029; called by muse, mutect2, varscan2
- VPS26C | c.*1868T>C | 3'UTR (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- ZFP91 | c.*2234G>C | 3'UTR (SNP) | VAF 7/148 reads (5%) | called by muse, mutect2
